Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A191, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A191-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid nodule.

PROCEDURE: Not answered.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

Carcinoma, Papillary, columnar cell 8344/3

Site Code: C73.9

ADDENDA:

FINAL DIAGNOSIS:

THYROID, TOTAL THYROIDECTOMY (23 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, COLUMNAR CELL VARIANT WITH SOLID AND MICROFOLLICULAR AREAS (see comment), LEFT LOBE, (2.0 CM), CONFINED TO THYROID; MARGINS FREE.
- B. ANGIOLYMPHATIC INVASION PRESENT.
- C. THREE LYMPH NODES (2- LEFT PERITHYROIDAL, AND 1 - ISTHMIC), NO TUMOR PRESENT (0/3).
- D. PATHOLOGIC STAGE: pT1bN0 (based on three lymph nodes).
- E. EXUBERANT CHRONIC LYMPHOCYTIC THYROIDITIS.

COMMENT:

This lesion is encapsulated, though there is capsular and vascular invasion, and encapsulation may not be relevant in this variant of papillary carcinoma. An immunostain for beta catenin is cytoplasmic only excluding cribriform morular variant.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Left Lobe
TUMOR FOCALITY: Unifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 2 cm
HISTOLOGIC TYPE**: Papillary carcinoma, columnar cell variant
PRIMARY TUMOR (pT): pT1b
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 3

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): Not applicable

EXTRATHYROIDAL EXTENSION: Not identified

MARGINS: Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS: Thyroiditis

Source: NCI Genomic Data Commons file 6357076e-c1de-4b65-b5f3-ac0e83eacaec (TCGA-BJ-A191.B78E5312-059F-441C-8C8D-932FA38812D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).